Gene-level copy-number profile of tumor specimen ALCH-AENC-TTP1-A from ALCHEMIST case ALCH-AENC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 66.2 years (24,173 days).
Specimen ALCH-AENC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c272bc64-e55e-4f13-a0ff-cddb6460cfb6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AENC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,244 have no estimate.
https://portal.gdc.cancer.gov/files/cfdcd75a-c4b3-4d57-b159-166442fd8649

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 59; copy number 1: 6; copy number 2: 474; copy number 3: 13,544; copy number 4: 8,407; copy number 5: 16,564; copy number 6: 14,030; copy number 7: 2,883; copy number 8: 1,801; copy number 9: 343; copy number 10: 104; copy number 11: 8; copy number 12: 1; copy number 13: 8; copy number 14: 2; copy number 15: 13; copy number 16: 4; copy number 36: 4; copy number 40: 3; copy number 41: 12; copy number 43: 7; copy number 44: 2; copy number 45: 6; copy number 47: 10; copy number 48: 6; copy number 50: 4; copy number 51: 1; copy number 52: 2; copy number 73: 3; copy number 82: 11; copy number 85: 12; copy number 88: 20; copy number 92: 11; copy number 95: 13; copy number 199: 1.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,362,019–12,418,090, 6 genes: FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P.
- chr17:20,999,596–22,706,703, 53 genes (within-gene range 0–3): USP22, AC087393.2, LINC01563, DHRS7B, TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 164 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,264,269–6,394,391, 2 genes, copy number 14: ACOT7, AL031848.2.
- chr1:6,634,168–6,730,012, 2 genes, copy number 15 (within-gene range 7–15): DNAJC11, LINC01672.
- chr1:7,915,871–8,344,167, 15 genes, copy number 11–15: TNFRSF9, AL009183.1, PARK7, Y_RNA, AL034417.4, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA.
- chr1:28,887,091–29,120,046, 4 genes, copy number 16 (within-gene range 7–16): EPB41, AL138785.1, Y_RNA, Metazoa_SRP.
- chr1:39,522,280–39,969,968, 23 genes, copy number 40–88 (within-gene range 7–88): PPIEL, PABPC4, PABPC4-AS1, SNORA55, HEYL, AL035404.2, NT5C1A, HPCAL4, PPIE, AL035404.1, RNU7-121P, BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1.
- chr5:165,220,577–165,241,756, 1 gene, copy number 13: LINC01938.
- chr6:99,082,449–99,082,761, 1 gene, copy number 43: AL078603.1.
- chr6:99,271,168–99,432,323, 4 genes, copy number 36: FAXC, COQ3, PNISR, AL513550.1.
- chr6:100,385,009–104,687,671, 16 genes, copy number 13–51: SIM1, SIM1-AS1, ASCC3, Z86062.1, AL133338.1, AL133338.2, GRIK2, ACTG1P18, AP002528.1, AP002530.1, AL357139.1, Z98755.1, AL591387.1, R3HDM2P2, NPM1P10, AL356967.1.
- chr6:104,864,464–107,459,564, 37 genes, copy number 43–199: LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, LINC02836, Z97206.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, LINC02526, LINC02532, RNU6-117P, MIR587, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr14:100,998,467–100,998,541, 1 gene, copy number 12: AL132709.6.
- chr14:105,546,610–105,601,728, 3 genes, copy number 13: ELK2BP, IGHA2, IGHE.
- chr14:105,621,116–105,669,843, 5 genes, copy number 11–13 (within-gene range 9–13): MIR8071-1, IGHG2, MIR8071-2, COPDA1, IGHGP.
- chr21:37,951,425–39,183,488, 26 genes, copy number 43–82: DSCR4, DSCR4-IT1, DSCR8, KCNJ15, AP001425.1, DSCR10, AP001434.1, SPATA20P1, LINC01423, ERG, SNRPGP13, AP001037.1, LINC00114, ETS2, AP001042.1, AP001042.2, AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.2, RPL23AP12, PCBP2P1, AF129408.2, PSMG1.
- chr21:39,216,624–39,219,805, 2 genes, copy number 45 (within-gene range 4–45): TIMM9P2, BRWD1-IT1.
- chr22:24,270,817–24,629,005, 12 genes, copy number 85: SPECC1L, SPECC1L-ADORA2A, ADORA2A, ADORA2A-AS1, UPB1, AP000355.1, GUCD1, SNRPD3, AP000356.5, LRRC75B, GGT1, AP000356.1.
- chr22:34,703,126–35,087,387, 4 genes, copy number 43–82: Z82196.1, Z82196.2, LINC02885, ISX.
- chr22:45,133,020–45,240,894, 6 genes, copy number 48: NUP50-DT, Z82243.1, NUP50, AL008718.3, KIAA0930, MIR1249.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
